Somatic mutation profile of tumor specimen TARGET-30-PATCJP-09A (aliquot TARGET-30-PATCJP-09A-01D) from TARGET case TARGET-30-PATCJP, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.3 years (1,561 days).
Specimen TARGET-30-PATCJP-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6334400a-7965-4925-adec-95e455a568ed.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PATCJP-10A (Blood Derived Normal), aliquot TARGET-30-PATCJP-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4e8ba3bd-0c1d-4bdc-b5a2-27c13b7f09a4

The open-access MAF lists 4 somatic variants for this specimen: 1 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 2, Missense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT4 | c.3235A>C p.K1079Q | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- ACP3 | c.1077G>T p.L359= | Silent (SNP) | VAF 29/90 reads (32%) | catalogued as COSV60485425; called by muse, mutect2, varscan2
- REV3L | c.6048C>T p.Y2016= | Silent (SNP) | VAF 79/154 reads (51%) | catalogued as rs753982547, COSV62617280; called by muse, varscan2
- FOXP2 | c.1094+25G>T | Intron (SNP) | VAF 45/93 reads (48%) | catalogued as rs939563150, COSV63484165; called by muse, mutect2, varscan2
